Somatic mutation profile of tumor specimen TARGET-10-PARDCY-09A (aliquot TARGET-10-PARDCY-09A-01D) from TARGET case TARGET-10-PARDCY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,493 days).
Specimen TARGET-10-PARDCY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b04dc8ed-922f-4901-b3d9-170152fd5d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDCY-10A (Blood Derived Normal), aliquot TARGET-10-PARDCY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b673cbb8-e0c5-41bb-bffa-9a55b70e5f89

The open-access MAF lists 12 somatic variants for this specimen: 12 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAAT | c.1051A>G p.N351D | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs1435770888; called by muse, mutect2
- OR8D2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV62488810; called by muse, mutect2
- PCDHA12 | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as COSV56534182; called by muse, mutect2, varscan2
- SORCS1 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV53861780; called by muse, mutect2
- CCDC39 | c.1395G>A p.M465I | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2
- FREM1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRTM4 | c.486G>T p.L162F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUP58 | c.428C>A p.T143N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- ODAPH | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2
- SLFN11 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- TLL1 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 7/138 reads (5%) | called by muse, mutect2
- ZKSCAN4 | c.1433G>T p.W478L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
